Somatic mutation profile of tumor specimen MMRF_1564_1_BM_CD138pos (aliquot MMRF_1564_1_BM_CD138pos_T2_KBS5U_L05369) from MMRF case MMRF_1564, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 86.6 years (31,640 days).
Specimen MMRF_1564_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fce1253-9f9d-46f1-b3bd-33def7b8e582.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1564_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1564_1_PB_Whole_C3_KBS5U_L05356; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37b35ca9-4400-4ef4-98e6-e83983439a0b

The open-access MAF lists 145 somatic variants for this specimen: 60 protein-altering or splice-affecting, 21 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, 3'UTR 37, Silent 21, Intron 11, 5'Flank 7, 3'Flank 4, 5'UTR 4, Frame Shift Del 3, RNA 1, Splice Region 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 52/89 reads (58%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs1159726645, COSV65314425; called by muse, mutect2, varscan2
- ALG10 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs745684863; called by mutect2, varscan2
- DLGAP2 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs758266310, COSV70096397; called by muse, mutect2, varscan2
- DYSF | c.4207G>A p.V1403I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767049254; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GET3 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV54406550; called by muse, mutect2
- ICAM5 | c.1597G>A p.G533R | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs201577589; called by muse, mutect2, varscan2
- IGHV1-69D | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1367696485; called by muse, mutect2, varscan2
- IGHV2-70 | c.158T>C p.M53T | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs1555607329; called by muse, varscan2
- IGKV4-1 | c.56A>G p.Y19C | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs180851255; called by muse, varscan2
- IGLV3-1 | c.70A>C p.T24P | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs369545397; called by muse, varscan2
- IGLV3-1 | c.211A>C p.K71Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as rs371025428; called by muse, mutect2, varscan2
- IGSF9 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1454120236, COSV63642429; called by muse, mutect2, varscan2
- MAML3 | c.3083G>A p.R1028Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.966); catalogued as rs764526660; called by muse, mutect2, varscan2
- MFNG | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1378134004; called by muse, mutect2
- MIA2 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.382); catalogued as COSV54496696; called by muse, mutect2, varscan2
- MUC16 | c.42733G>A p.D14245N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.954); catalogued as rs1248689975; called by muse, mutect2, varscan2
- PELI2 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.989); catalogued as rs137897340; called by muse, mutect2, varscan2
- PUS1 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs768762075; called by muse, mutect2, varscan2
- RBMXL2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 173/266 reads (65%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV60979613; called by muse, mutect2, varscan2
- RBPMS2 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55603651; called by muse, mutect2, varscan2
- RNF4 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV58643033; called by muse, mutect2
- SLC35B3 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.179); catalogued as rs750043929, COSV59469836; called by muse, mutect2, varscan2
- TRABD | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.284); catalogued as rs1484740738; called by muse, mutect2, varscan2
- ABCC12 | c.2249C>T p.S750F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ABRA | c.281G>T p.S94I | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- AMER2 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ARHGAP26 | c.50A>C p.H17P | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.124); called by muse, mutect2
- ATG101 | c.578_580del p.S193del | In Frame Del (DEL) | VAF 66/205 reads (32%) | called by mutect2, pindel, varscan2
- BTBD8 | c.477T>A p.D159E | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COBLL1 | c.2931_2934del p.N977Kfs*18 (on ENST00000392717; = p.N939Kfs*18 on NM_014900.5) | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel, varscan2
- DLG5 | c.1383G>T p.K461N | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- DRC3 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRY | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- GGTA1 | c.116+4A>C | Splice Region (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- GPRIN1 | c.2666T>C p.V889A | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- KHNYN | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIAA0586 | c.901T>C p.F301L (on ENST00000619416 / NM_001244190.2; = p.F316L on NM_014749.5) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KLHL34 | c.1376T>A p.L459Q | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MLC1 | c.819C>A p.F273L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MSLNL | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRK | c.316A>T p.I106F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH15 | c.3516T>A p.D1172E | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH17 | c.3115C>A p.P1039T | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- PIEZO2 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, mutect2
- PLRG1 | c.1310A>T p.H437L | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- RPS18 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- SRMS | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SV2C | c.84G>T p.K28N | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TAF3 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TBC1D32 | c.2762G>A p.G921D | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENT5C | c.104del p.I35Tfs*12 | Frame Shift Del (DEL) | VAF 78/211 reads (37%) | called by pindel, varscan2
- TENT5C | c.661_686del p.E221Tfs*54 | Frame Shift Del (DEL) | VAF 14/123 reads (11%) | called by mutect2, pindel
- TRIM49C | c.941A>C p.D314A | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- TUSC3 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UBE2N | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- XIRP2 | c.1882G>C p.G628R (on ENST00000628543; = p.G803R on NM_152381.6) | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.2336C>T p.S779L (on ENST00000628543; = p.S954L on NM_152381.6) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- ZDHHC14 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZNF638 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADAMTS16 | c.3648C>T p.C1216= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP10 | c.219T>G p.G73= | Silent (SNP) | VAF 66/86 reads (77%) | called by muse, mutect2, varscan2
- BANP | c.27T>C p.D9= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs1025003110; called by muse, mutect2, varscan2
- DEGS1 | c.531C>T p.I177= | Silent (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- ETAA1 | c.2514T>C p.N838= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- GPR33 | c.537C>T p.C179= | Silent (SNP) | VAF 24/83 reads (29%) | called by muse, mutect2, varscan2
- HOXA3 | c.417C>T p.N139= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs774936035; called by muse, mutect2, varscan2
- IGHJ4 | c.45A>T p.S15= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs141539541; called by muse, varscan2
- IGHV2-70 | c.144C>T p.L48= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs72690596; called by muse, varscan2
- IGKJ5 | c.39A>G p.K13= | Silent (SNP) | VAF 56/120 reads (47%) | catalogued as rs373270263; called by muse, varscan2
- IGLV3-25 | c.261A>T p.T87= | Silent (SNP) | VAF 14/108 reads (13%) | called by muse, varscan2
- MRGPRX4 | c.222C>T p.L74= | Silent (SNP) | VAF 47/265 reads (18%) | called by muse, mutect2, varscan2
- MYO10 | c.5781G>A p.K1927= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as COSV57016127; called by muse, mutect2, varscan2
- NKPD1 | c.378G>A p.A126= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs145321228; called by muse, mutect2, varscan2
- NUFIP1 | c.129G>A p.L43= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV63151043; called by muse, mutect2, varscan2
- OR2AK2 | c.810G>C p.R270= | Silent (SNP) | VAF 36/109 reads (33%) | called by muse, mutect2, varscan2
- RNF222 | c.381C>T p.G127= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- STARD8 | c.1974C>T p.S658= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- TAS2R30 | c.954C>T p.V318= | Silent (SNP) | VAF 108/341 reads (32%) | called by muse, mutect2, varscan2
- THEMIS | c.444A>C p.I148= | Silent (SNP) | VAF 65/109 reads (60%) | called by muse, mutect2, varscan2
- ZBTB12 | c.522T>A p.P174= | Silent (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- AC004947.2 | chr7:26533600 G>T | 5'Flank (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- ACAD10 | c.*293C>T | 3'UTR (SNP) | VAF 88/236 reads (37%) | catalogued as rs1167840702; called by muse, mutect2, varscan2
- ACSL6 | c.49+14C>A | Intron (SNP) | VAF 41/128 reads (32%) | called by muse, mutect2, varscan2
- ACTG1 | c.-29T>C | 5'UTR (SNP) | VAF 16/157 reads (10%) | catalogued as rs369675938; called by muse, mutect2
- ADAMTS2 | c.*2456C>T | 3'UTR (SNP) | VAF 34/117 reads (29%) | catalogued as rs777395144; called by muse, mutect2, varscan2
- ADH5P5 | chr5:23980042 C>G | 5'Flank (SNP) | VAF 33/242 reads (14%) | called by muse, mutect2, varscan2
- ADNP2 | c.*1420T>G | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- ANKRD40 | c.*2608T>A | 3'UTR (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504636 ins AGTC | 5'Flank (INS) | VAF 33/200 reads (17%) | called by mutect2, pindel, varscan2
- ARF1 | chr1:228103426 C>A | 3'Flank (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- ARFIP2 | c.537+149G>A | Intron (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.*327G>A | 3'UTR (SNP) | VAF 24/118 reads (20%) | called by muse, mutect2, varscan2
- ASB10 | chr7:151187288 C>A | 5'Flank (SNP) | VAF 33/234 reads (14%) | called by muse, mutect2, varscan2
- ATP5MC2 | c.-160G>A | 5'UTR (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- BARD1 | c.*36C>T | 3'UTR (SNP) | VAF 66/195 reads (34%) | called by muse, mutect2, varscan2
- CACNA1A | c.784+49C>A | Intron (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- CALN1 | c.*2187G>T | 3'UTR (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- CCDC146 | chr7:77121960 C>T | 5'Flank (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- CEACAM1 | c.*278C>T | 3'UTR (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- CYP19A1 | c.*2300A>T | 3'UTR (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- DGKB | c.1287+120_1287+123del | Intron (DEL) | VAF 5/20 reads (25%) | catalogued as rs1305469313; called by mutect2, varscan2
- DPH1 | c.62-19G>A | Intron (SNP) | VAF 54/144 reads (38%) | called by muse, mutect2, varscan2
- DSC2 | c.*45T>A | 3'UTR (SNP) | VAF 35/92 reads (38%) | catalogued as rs760835926, COSV99199491; called by muse, mutect2, varscan2
- EIF3M | c.*3614del | 3'UTR (DEL) | VAF 14/111 reads (13%) | catalogued as rs201183779; called by pindel, varscan2
- ELN | chr7:74069048 G>A | 3'Flank (SNP) | VAF 22/56 reads (39%) | catalogued as rs1034599176; called by muse, mutect2, varscan2
- ENDOD1 | c.*91A>G | 3'UTR (SNP) | VAF 27/139 reads (19%) | called by muse, mutect2, varscan2
- FAM20B | c.*1131G>A | 3'UTR (SNP) | VAF 26/44 reads (59%) | called by muse, mutect2, varscan2
- FAM98B | c.*1908A>G | 3'UTR (SNP) | VAF 2/13 reads (15%) | called by muse, mutect2
- GPD2 | c.*884A>C | 3'UTR (SNP) | VAF 12/35 reads (34%) | catalogued as rs568681265; called by muse, mutect2, varscan2
- HERPUD1 | c.*43A>T | 3'UTR (SNP) | VAF 37/135 reads (27%) | called by muse, mutect2, varscan2
- HGF | c.*401T>G | 3'UTR (SNP) | VAF 69/126 reads (55%) | catalogued as rs1451427168; called by muse, mutect2, varscan2
- HS3ST5 | c.*252del | 3'UTR (DEL) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- HSPA12A | c.*1897A>G | 3'UTR (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- INPP4B | chr4:142027754 A>C | 3'Flank (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- INVS | c.273+4244T>C | Intron (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- LYG1 | c.*112T>C | 3'UTR (SNP) | VAF 11/121 reads (9%) | catalogued as COSV57915191; called by muse, mutect2
- LYRM2 | c.*2444C>T | 3'UTR (SNP) | VAF 29/60 reads (48%) | catalogued as rs1315289522; called by muse, mutect2, varscan2
- MAP1LC3C | c.*52A>G | 3'UTR (SNP) | VAF 15/80 reads (19%) | catalogued as rs878968001; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851126 T>A | 5'Flank (SNP) | VAF 18/164 reads (11%) | catalogued as rs569234583; called by muse, varscan2
- MMP16 | c.*5075dup | 3'UTR (INS) | VAF 12/30 reads (40%) | called by mutect2, pindel, varscan2
- MSRB3 | c.*1137A>G | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- MUSK | c.628+8701T>C | Intron (SNP) | VAF 27/163 reads (17%) | called by muse, mutect2, varscan2
- MYL6 | c.3+134A>G | Intron (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
- NFIB | c.*1736C>T | 3'UTR (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- OPCML | c.*3750C>T | 3'UTR (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- OR5T1 | c.*160A>C | 3'UTR (SNP) | VAF 38/66 reads (58%) | called by muse, mutect2, varscan2
- RASSF8 | chr12:26072521 T>G | 3'Flank (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- RBM48 | c.1017+603A>C | Intron (SNP) | VAF 17/113 reads (15%) | catalogued as rs893755264; called by muse, mutect2, varscan2
- SBK1 | c.*299C>T | 3'UTR (SNP) | VAF 8/47 reads (17%) | catalogued as rs1473131759; called by muse, varscan2
- SFRP1 | c.*1835C>T | 3'UTR (SNP) | VAF 35/75 reads (47%) | catalogued as rs1389165121; called by muse, mutect2, varscan2
- SHISA9 | c.563+6860G>T | Intron (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- SLC35F5 | c.-27C>T | 5'UTR (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- SMIM15 | c.*65_*66del | 3'UTR (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel
- SORBS1 | c.3640-37C>T | Intron (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- SP5 | chr2:170712989 G>A | 5'Flank (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- SSPOP | n.10827G>A | RNA (SNP) | VAF 31/117 reads (26%) | catalogued as rs781227305, COSV65131497; called by muse, mutect2, varscan2
- STK38L | c.*2604_*2605del | 3'UTR (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- TFCP2L1 | c.*4253G>T | 3'UTR (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- THRB | c.*4237G>C | 3'UTR (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- TNS3 | c.*1130C>A | 3'UTR (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- TWNK | c.-641T>G | 5'UTR (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*1014T>A | 3'UTR (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- VCPIP1 | c.*303A>G | 3'UTR (SNP) | VAF 17/61 reads (28%) | catalogued as rs1173162648; called by muse, mutect2, varscan2
- ZNF572 | c.*544G>A | 3'UTR (SNP) | VAF 13/33 reads (39%) | catalogued as rs1564127385; called by muse, mutect2, varscan2
